Somatic mutation profile of tumor specimen TCGA-D8-A1JI-01A (aliquot TCGA-D8-A1JI-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.0 years (20,072 days).
Specimen TCGA-D8-A1JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98867b8e-f7e1-4a03-8b3b-2a9b8fb3014f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JI-10A (Blood Derived Normal), aliquot TCGA-D8-A1JI-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac21dd76-e95d-4658-b545-8dfea6b868fd

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 19, Silent 11, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.47dup p.Y16* | Nonsense Mutation (INS) | VAF 68/112 reads (61%) | hotspot (GDC flag); catalogued as rs876661009, CI077458, COSV64293657; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- C1orf112 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV53683320; called by muse, mutect2, varscan2
- CENPE | c.4622G>A p.S1541N | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV99478004; called by muse, mutect2
- CFAP45 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63651348; called by muse, mutect2, varscan2
- DICER1 | c.4529G>A p.C1510Y | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58629287; called by muse, mutect2, varscan2
- EXOSC7 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs774989692, COSV55558007; called by mutect2, varscan2
- LCE2C | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.582); catalogued as rs778531570, COSV100909439; called by muse, mutect2
- LONRF3 | c.1465A>G p.K489E (on ENST00000371628 / NM_001031855.3; = p.K448E on NM_024778.5) | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV59157336; called by muse, mutect2, varscan2
- MAGED1 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV58517074; called by muse, mutect2, varscan2
- NEB | c.9416A>G p.N3139S | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV51465004; called by muse, varscan2
- OSBPL9 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1193625406, COSV61875475; called by muse, mutect2, varscan2
- PKD1 | c.10775G>T p.S3592I (on ENST00000262304 / NM_001009944.3; = p.S3591I on NM_000296.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs772917917, COSV51927080; called by muse, mutect2, varscan2
- PPFIA1 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV54141388; called by muse, mutect2, varscan2
- RAB1B | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV100270613, COSV100270620, COSV57584627; called by muse, varscan2
- SCN8A | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100633761, COSV61993883; called by muse, mutect2
- SCN8A | c.4538G>A p.G1513E | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV61983075; called by muse, mutect2, varscan2
- SLC17A2 | c.361dup p.M121Nfs*21 | Frame Shift Ins (INS) | VAF 55/131 reads (42%) | catalogued as rs770669846; called by mutect2, varscan2
- SPATA13 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV57981967; called by muse, mutect2, varscan2
- TECTA | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.516); catalogued as COSV50823285; called by muse, mutect2, varscan2
- TKT | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 129/305 reads (42%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.683); catalogued as COSV99965029; called by muse, mutect2, varscan2
- TRAF7 | c.1386+2T>C p.X462_splice | Splice Site (SNP) | VAF 52/114 reads (46%) | catalogued as COSV58218778; called by muse, mutect2, varscan2
- VPS13C | c.1367G>A p.G456E (on ENST00000644861 / NM_020821.3; = p.G413E on NM_017684.5) | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748754522, COSV51427834; called by muse, mutect2, varscan2
- ZNF236 | c.2950C>T p.Q984* | Nonsense Mutation (SNP) | VAF 46/110 reads (42%) | catalogued as COSV53499219; called by muse, mutect2, varscan2
- ARID1A | c.2173_2186delinsG p.P725Afs*13 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | called by pindel, varscan2*
- CCDC136 | c.3336C>T p.N1112= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV52806022; called by muse, mutect2, varscan2
- CDK3 | c.177G>A p.K59= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV56916769; called by muse, mutect2, varscan2
- CWC27 | c.456C>T p.D152= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs373443413, COSV66884137; called by muse, mutect2, varscan2
- DMRTB1 | c.657G>A p.P219= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1183292973, COSV65114152; called by muse, mutect2, varscan2
- FAM122B | c.261T>C p.D87= | Silent (SNP) | VAF 76/162 reads (47%) | catalogued as COSV53232670; called by muse, mutect2, varscan2
- FURIN | c.1083G>A p.T361= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs752150238, COSV51577022; called by muse, mutect2, varscan2
- ITGA2 | c.283C>T p.L95= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV99670428; called by muse, mutect2, varscan2
- KLC2 | c.1428C>T p.S476= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV57582526; called by muse, varscan2
- MINDY4 | c.1161A>G p.E387= | Silent (SNP) | VAF 78/192 reads (41%) | catalogued as rs1239924910, COSV54678919; called by muse, mutect2, varscan2
- PTPRB | c.5490G>T p.L1830= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV54255598; called by muse, mutect2, varscan2
- WFDC2 | c.270C>T p.L90= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs200993376, COSV54152131; called by muse, mutect2, varscan2
